Gene-level copy-number profile of tumor specimen TCGA-49-6745-01A from TCGA case TCGA-49-6745, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IIIA; Age at diagnosis: 82.5 years (30,133 days).
Specimen TCGA-49-6745-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUAD.06a2b6c8-6306-43a8-9008-937c4d8995d9.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-49-6745-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 805 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/2480876b-3ca2-43c4-9a7e-9e96f3b89d27

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 5,014; copy number 2: 48,818; copy number 3: 2,313; copy number 4: 3,014; copy number 5: 62; copy number 6: 122; copy number 7: 102; copy number 8: 211; copy number 9: 9; copy number 10: 32; copy number 13: 96; copy number 15: 25.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-49-6745-01A-11D-1854-01): tumor purity 0.24, ploidy 3.83, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 659 genes in 9 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:69,999,550–72,740,525, 39 genes, copy number 8 (within-gene range 3–8): SAMMSON, AC139700.1, UQCRHP4, MDFIC2, AC104633.1, AC104633.2, COX6CP6, HMGB1P36, RNU6-281P, FOXP1, AC097634.4, FOXP1-AS1, MIR1284, AC097634.2, FOXP1-IT1, AC097634.3, AC097634.1, EIF4E3, GPR27, PROK2, AC096970.1, RN7SL271P, LINC00877, UBE2Q2P9, AC105265.2, AC105265.3, AC105265.1, CCDC137P, LINC00870, AC112219.2, AC112219.1, AC134508.2, AC134508.1, RYBP, AC104435.2, RNU1-62P, AC104435.1, RNA5SP136, AC097369.4.
- chr3:84,638,405–91,513,775, 49 genes, copy number 5: LINC00971, AC117482.1, LINC02025, AC132660.2, CADM2, MIR5688, CADM2-AS2, CADM2-AS1, THAP12P2, AC107024.1, RNU6-1129P, AC108733.1, RN7SKP284, LINC02070, AC108706.1, VGLL3, PPATP1, LINC00506, MIR4795, CHMP2B, POU1F1, KRT8P25, APOOP2, PSMC1P6, AC108749.1, RNU6-873P, HTR1F, RNU6ATAC6P, CGGBP1, AC119733.1, ZNF654, CBX5P1, C3orf38, ABCF2P1, CSNKA2IP, Y_RNA, NDUFA5P5, ICE2P2, GAPDHP50, EPHA3, AC109129.1, MTCO2P6, MTCO1P6, U3, RNU6-712P, PROS2P, HSPE1P19, ABBA01000933.1, ABBA01000935.2.
- chr12:16,188,485–34,249,958, 314 genes, copy number 5–13 (broad region; genes not listed).
- chr12:48,168,847–49,324,576, 72 genes, copy number 8 (broad region; genes not listed).
- chr12:51,093,656–51,173,135, 1 gene, copy number 8 (within-gene range 2–9): TFCP2.
- chr12:51,124,628–51,515,763, 11 genes, copy number 8–9 (within-gene range 2–9): PHBP19, Y_RNA, POU6F1, AC139768.1, DAZAP2, SMAGP, BIN2, CELA1, GALNT6, SLC4A8, AC107031.1.
- chr12:57,529,633–58,813,060, 44 genes, copy number 8 (within-gene range 2–8): DCTN2, KIF5A, PIP4K2C, DTX3, ARHGEF25, AC025165.1, AC025165.6, SLC26A10, B4GALNT1, RPL13AP23, OS9, AC025165.2, AGAP2, AGAP2-AS1, TSPAN31, CDK4, MIR6759, MARCHF9, CYP27B1, METTL1, EEF1AKMT3, AC025165.3, TSFM, AVIL, AC025165.5, RNU6-1083P, AC025165.4, CTDSP2, MIR26A2, AC083805.2, AC083805.1, AC083805.3, ATP23, GIHCG, AC084033.1, RN7SKP65, AC084033.2, LINC02403, AC090643.1, AC090643.2, RPL21P103, AC025578.1, AC020637.1, LINC02388.
- chr12:67,929,235–75,511,636, 128 genes, copy number 6–15 (broad region; genes not listed).
- chr12:75,600,047–75,601,551, 1 gene, copy number 10: AC022507.1.

Autosomal genes at a single copy (total copy number 1): 2,628. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
